CCDI case PBCGTD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/728404a9-18dd-4355-a7cd-019d49deb5b8

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 1.6 years (571 days).

Biospecimens (3 samples)
- Sample 0DSKZF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DSKZL, 0DSL0G (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
